Gene-level copy-number profile of tumor specimen TCGA-59-2348-01A from TCGA case TCGA-59-2348, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-59-2348-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.abf2071b-b577-4dce-9e96-8ee1dcc83236.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-59-2348-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8208494b-559d-4a04-8181-5b996b8b1f73

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,282; copy number 2: 13,263; copy number 3: 21,627; copy number 4: 11,730; copy number 5: 5,001; copy number 6: 3,740; copy number 7: 1,501; copy number 8: 520; copy number 9: 75; copy number 10: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-59-2348-01A-01D-0704-01): tumor purity 0.63, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,159 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,298,366–84,893,206, 17 genes, copy number 7 (within-gene range 5–7): SAMD13, AL359273.2, UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP, AC104169.1, LPAR3.
- chr1:153,789,030–153,923,360, 1 gene, copy number 7 (within-gene range 6–7): GATAD2B.
- chr1:153,852,106–154,870,281, 52 genes, copy number 7: AL513523.1, AL831737.1, AL358472.5, DENND4B, CRTC2, SLC39A1, AL358472.7, MIR6737, AL358472.4, AL358472.3, CREB3L4, JTB, AL358472.6, AL358472.2, RAB13, RPS27, NUP210L, AL358472.1, RNU6-179P, RPS7P2, MIR5698, TPM3, RN7SL431P, MIR190B, C1orf189, C1orf43, UBAP2L, SNORA58B, HAX1, AL354980.1, RNU6-239P, RNU6-121P, AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17, IL6R-AS1, IL6R, PSMD8P1, SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1, AL592078.2, CHRNB2, AL592078.1, ADAR, AL606500.1, KCNN3.
- chr1:182,409,192–182,560,599, 1 gene, copy number 9 (within-gene range 6–9): RGSL1.
- chr1:182,573,634–183,928,532, 32 genes, copy number 9 (within-gene range 6–9): RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1.
- chr1:195,747,024–203,024,848, 147 genes, copy number 7–8 (broad region; genes not listed).
- chr2:177,111,036–198,772,356, 279 genes, copy number 7 (broad region; genes not listed).
- chr4:10,006,482–10,009,725, 1 gene, copy number 7: SLC2A9-AS1.
- chr8:98,906,260–101,224,573, 63 genes, copy number 10 (broad region; genes not listed).
- chr10:4,871,901–5,499,570, 22 genes, copy number 7: AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5.
- chr10:72,096,032–78,178,186, 156 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr11:34,709,600–34,743,199, 2 genes, copy number 9: AC087783.1, AL359999.1.
- chr11:47,437,764–49,018,589, 54 genes, copy number 7 (within-gene range 6–7): RAPSN, CELF1, AC090559.2, RN7SL652P, NDUFS3, PTPMT1, KBTBD4, RNU5E-10P, KF459542.1, FAM180B, C1QTNF4, MTCH2, AGBL2, FNBP4, Y_RNA, NUP160, AC021443.1, RNA5SP340, Y_RNA, YPEL5P2, AC023232.1, PTPRJ, PTPRJ-AS1, MIR3161, OR4B1, OR4B2P, OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5, OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1.
- chr11:78,015,715–78,444,049, 16 genes, copy number 7 (within-gene range 2–7): AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2.
- chr12:7,919,230–7,995,084, 4 genes, copy number 7: SLC2A3, AC006511.6, Y_RNA, AC006511.1.
- chr12:28,133,249–41,574,745, 171 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr12:46,358,188–46,373,778, 2 genes, copy number 8: SLC38A2, AC025031.2.
- chr12:46,384,233–46,407,166, 3 genes, copy number 8: AC025031.1, AC025031.4, AC025031.5.
- chr12:53,739,611–54,034,888, 22 genes, copy number 8 (within-gene range 5–8): AC076968.2, CISTR, AC076968.1, RN7SKP289, HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3, HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8.
- chr12:59,450,673–64,222,296, 65 genes, copy number 8 (broad region; genes not listed).
- chr12:64,228,560–64,228,675, 1 gene, copy number 8: RNU5A-7P.
- chr14:99,945,315–100,861,031, 38 genes, copy number 7 (within-gene range 6–7): RNU1-47P, VDAC3P1, EVL, AL133368.1, AL133368.2, AL157912.1, MIR151B, MIR342, DEGS2, AL133523.1, YY1, AL157871.5, MIR6764, AL157871.6, SLC25A29, AL157871.1, MIR345, RN7SL523P, SLC25A47, AL157871.4, WARS1, AL157871.2, AL157871.3, WDR25, AL135838.1, AL845552.1, RN7SKP92, BEGAIN, AL845552.2, AL163974.1, LINC00523, AL132711.1, DLK1, MEG3, MIR2392, AL117190.5, AL117190.3, AL117190.7.
- chr14:103,121,476–106,875,071, 303 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr18:24,460,637–28,177,946, 55 genes, copy number 7: HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1.
- chr19:12,875,209–16,880,353, 210 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr19:52,555,457–52,587,174, 1 gene, copy number 8 (within-gene range 5–8): ZNF701.
- chr19:52,575,883–54,063,953, 133 genes, copy number 8 (broad region; genes not listed).
- chr20:51,596,514–64,313,132, 308 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,282. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
